Gene-level copy-number profile of tumor specimen TCGA-D7-6526-01A from TCGA case TCGA-D7-6526, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 67.0 years (24,477 days).
Specimen TCGA-D7-6526-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.db473114-8195-492e-8cec-05837f9ee5ef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-6526-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/82609de1-258b-4285-bd5c-92afc920f871

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 144; copy number 2: 2,642; copy number 3: 6,725; copy number 4: 17,363; copy number 5: 11,890; copy number 6: 9,357; copy number 7: 5,626; copy number 8: 2,749; copy number 9: 415; copy number 10: 1,497; copy number 11: 219; copy number 12: 35; copy number 13: 373; copy number 14: 46; copy number 16: 188; copy number 18: 16; copy number 19: 94; copy number 20: 148; copy number 22: 49; copy number 27: 115; copy number 32: 9; copy number 36: 20; copy number 48: 29; copy number 55: 12; copy number 56: 33; copy number 69: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-6526-01A-11D-1799-01): tumor purity 0.6, ploidy 4.7, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:18,370,607–18,383,917, 2 genes: NATP, AC025062.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,308 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:99,646,113–100,641,723, 35 genes, copy number 9 (within-gene range 4–9): PALMD, HMGB3P10, FRRS1, RNU4-75P, Y_RNA, AC096949.1, AGL, AC118553.1, SLC35A3, AC118553.2, RNU6-750P, RNU6-1318P, MFSD14A, AC093019.2, SASS6, AC093019.1, TRMT13, LRRC39, DBT, RPL23AP90, BRI3P1, AL445928.2, AL445928.1, RTCA-AS1, RTCA, MIR553, AC104457.1, AC104457.2, CDC14A, BCAS2P2, AL589990.1, GPR88, AC099670.1, LINC01349, AC099670.3.
- chr7:63,011,463–66,995,587, 188 genes, copy number 19–27 (broad region; genes not listed).
- chr7:84,847,877–85,636,344, 10 genes, copy number 16: AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1.
- chr7:86,643,914–97,437,896, 163 genes, copy number 9–10 (broad region; genes not listed).
- chr7:102,813,230–103,074,843, 1 gene, copy number 36 (within-gene range 7–36): FBXL13.
- chr7:102,857,450–105,876,604, 48 genes, copy number 36–48 (within-gene range 7–48): RN7SKP198, LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86, ORC5, LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1.
- chr7:106,035,798–107,202,522, 19 genes, copy number 19: AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1.
- chr7:115,789,729–117,323,152, 43 genes, copy number 56–69: AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2.
- chr7:122,676,580–123,877,481, 21 genes, copy number 32–55: AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4.
- chr8:73,294,602–140,458,579, 923 genes, copy number 10–19 (within-gene range 3–19) (broad region; genes not listed).
- chr9:32,384,603–36,487,548, 191 genes, copy number 10–13 (within-gene range 2–13) (broad region; genes not listed).
- chr9:136,992,422–138,203,325, 66 genes, copy number 10 (broad region; genes not listed).
- chr11:77,821,109–77,918,432, 1 gene, copy number 11 (within-gene range 5–11): AAMDC.
- chr11:77,866,412–89,727,253, 179 genes, copy number 9–11 (within-gene range 7–11) (broad region; genes not listed).
- chr11:90,731,110–107,738,718, 248 genes, copy number 10 (broad region; genes not listed).
- chr11:120,325,296–123,036,224, 44 genes, copy number 9 (within-gene range 8–9): TLCD5, ARHGEF12, 7SK, GRIK4, ELOCP22, AP004147.1, HMGB1P42, TBCEL, TBCEL-TECTA, TECTA, AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1, AP001977.1, AP001924.1, RNU6-256P, AP001924.2, MIR100HG, MIR125B1, BLID, MIRLET7A2, MIR100, AP000755.1, AP000755.2, RNU4ATAC10P, RNU4ATAC5P, RNU6-592P, GLULP3, AP002469.1, UBASH3B, AP002762.3, AP002762.1, AP002762.2, CRTAM, JHY, RNU4-23P, ATP5PBP5, BSX, AP003040.1, RPL34P23.
- chr12:47,661,249–48,040,761, 24 genes, copy number 9: RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5, AC004801.4, AC004801.3, AC004801.6.
- chr12:48,054,813–48,055,591, 1 gene, copy number 9: AC004801.2.
- chr13:30,196,443–41,506,248, 181 genes, copy number 9–12 (broad region; genes not listed).
- chr13:95,677,139–95,794,988, 1 gene, copy number 14 (within-gene range 5–14): DNAJC3.
- chr13:95,744,726–98,024,296, 27 genes, copy number 14 (within-gene range 5–14): AL138955.1, UGGT2, HMGN1P24, HS6ST3, RN7SL164P, MIR4501, AMMECR1LP1, HSP90AB6P, TULP3P1, AL353581.1, RN7SKP7, OXGR1, LINC00456, MBNL2, AL161430.1, RNA5SP37, AL442067.3, RAP2A, AL442067.1, AL442067.2, PSMA6P4, AL359502.1, AL359502.2, RPL7AP61, AL356580.1, IPO5, FTLP8.
- chr14:95,181,940–95,319,908, 1 gene, copy number 14 (within-gene range 6–14): CLMN.
- chr14:95,199,039–95,475,836, 4 genes, copy number 14 (within-gene range 6–14): AL117187.1, AL117187.2, LINC02292, SYNE3.
- chr17:38,702,262–41,190,639, 152 genes, copy number 13–16 (broad region; genes not listed).
- chr19:16,283,359–16,353,182, 3 genes, copy number 10: AC020911.2, KLF2, AC020917.3.
- chr19:16,356,329–16,358,327, 1 gene, copy number 10: AC020917.4.
- chr19:27,638,483–32,676,597, 94 genes, copy number 14–22 (within-gene range 2–22) (broad region; genes not listed).
- chr19:33,386,950–41,261,766, 397 genes, copy number 10–20 (within-gene range 2–20) (broad region; genes not listed).
- chr19:44,846,175–46,231,243, 83 genes, copy number 10 (broad region; genes not listed).
- chr19:49,635,292–49,840,383, 18 genes, copy number 12: RRAS, SCAF1, IRF3, BCL2L12, PRMT1, MIR5088, ADM5, AC011495.3, CPT1C, AC011495.1, TSKS, RNU6-841P, AP2A1, MIR6799, FUZ, AC006942.1, MED25, MIR6800.
- chr20:57,391,396–60,083,872, 66 genes, copy number 11–20 (within-gene range 8–20) (broad region; genes not listed).
- chr20:60,308,474–60,308,567, 1 gene, copy number 20: MIR646.
- chr22:33,014,980–34,218,796, 15 genes, copy number 9: Z83846.1, LINC01640, Z82198.1, Z82198.3, LARGE1, Z82198.2, Z82173.1, MIR4764, SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1, LINC01643, Z68323.1.
- chr22:38,290,691–38,656,629, 13 genes, copy number 11 (within-gene range 5–11): CSNK1E, TPTEP2-CSNK1E, TPTEP2, Z98749.1, Z97056.2, Z97056.1, KCNJ4, Z97056.3, KDELR3, DDX17, DMC1, RPS29P31, FAM227A.
- chr22:43,411,196–45,413,619, 46 genes, copy number 9–18 (within-gene range 2–18): MPPED1, BX546033.1, EFCAB6-AS1, EFCAB6, Z97055.1, HMGN2P9, Z97055.2, SULT4A1, PNPLA5, PNPLA3, SAMM50, RPL35AP36, PARVB, AL033543.1, AL031595.3, PARVG, AL031595.1, AL031595.2, SHISAL1, Z85994.1, Z85994.2, LINC01656, MRPS18CP6, AL023973.1, RTL6, KRT18P23, LINC00207, LINC00229, ANP32BP2, PRR5, PRR5-ARHGAP8, ARHGAP8, PHF21B, Z83838.1, AL079301.1, NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A, FAM118A, SMC1B.

Autosomal genes at a single copy (total copy number 1): 143. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
